Surgical pathology report (de-identified scan), TCGA case TCGA-34-5241, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-5241-01A (Primary Tumor).

FINAL DIAGNOSIS:**Summary Statement**

The right lower lobectomy reveals an invasive 6.0 cm moderately differentiated squamous cell carcinoma associated with angiolymphatic and visceral pleural invasion, but without involvement of N1 or N2 lymph nodes. All margins free. Pathologic stage T2 N0 MX.

PART 1: LYMPH NODE, LEVEL 9 LYMPH NODE, BIOPSY -

SOLITARY FRAGMENT OF LYMPH NODE WITH REACTIVE CHANGE AND NO EVIDENCE OF METASTATIC CARCINOMA. ✓

PART 2: LYMPH NODE, "LEVEL 11 LYMPH NODE NEAR BASILAR ARTERY", BIOPSY -

SEVEN FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY. ✓

PART 3: LYMPH NODE, LEVEL 11 NEAR BIFURCATION MIDDLE LOBE, BIOPSY -

- A. SEVEN FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE INCLUDING ANTHRACOSILICOTIC NODULES AND A SINGLE FIBROCASEOCALCIFIC GRANULOMA. GROCOTT AND ACID-FAST STAINS FOR MICROORGANISMS ARE POSITIVE FOR FOUR MICRON OVAL YEAST FORMS SUGGESTIVE OF HISTOPLASMA. CORRELATION WITH CULTURE RESULTS SUGGESTED.
- B. NO EVIDENCE OF MALIGNANCY.

PART 4: LYMPH NODE, LEVEL 11 LYMPH NODE NEAR BASILAR BRONCHUS, BIOPSY -

TWO FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 5: LUNG, RIGHT LOWER LOBE, LOBECTOMY -

- A. MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 6.0 CM IN DIAMETER, WITH ANGIOLYMPHATIC AND VISCERAL PLEURAL INVASION. ALL MARGINS FREE. MILD HOST LYMPHOCYTIC RESPONSE. PATHOLOGIC STAGE T2 N0 MX.
- B. SIXTEEN N1 LYMPH NODES WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.
- C. EMPHYSEMATOUS CHANGE ASSOCIATED WITH OSSEOUS METAPLASIA.
- D. FOCAL POST-OBSTRUCTIVE PNEUMONIA.

PART 6: LYMPH NODE, RIGHT LEVEL 4 LYMPH NODE, BIOPSY -

BENIGN FRAGMENTS OF FIBROADIPOSE TISSUE AND NERVE. NO LYMPH NODE IDENTIFIED.

PART 7: LYMPH NODE, RIGHT LEVEL 7 NODE, BIOPSY -

FOUR FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY. ✓

PART 8: BRONCHUS, LEFT MAINSTEM, BIOPSY -

FRAGMENT OF BRONCHIAL MUCOSA WITH SQUAMOUS METAPLASIA WITH BASAL CELL HYPERPLASIA WITH SUBMUCOSAL ACUTE AND CHRONIC INFLAMMATION. NO EVIDENCE OF MALIGNANCY.

PART 9: CARINA, BIOPSY -

FRAGMENTS OF BRONCHIAL MUCOSA WITH SQUAMOUS METAPLASIA AND BASAL CELL HYPERPLASIA WITH SUBMUCOSAL AND CHRONIC INFLAMMATION. NO EVIDENCE OF MALIGNANCY.

COMMENT:

PAS / PAS-D and mucicarmlne stains are negative. Elastic tissue stains show pleural invasion.

The squamous cell carcinoma shows an interesting pattern of subpleural growth, in a lepidic fashion, with lymphatic infiltration. In these areas, it tracks along the visceral pleural surface, which seems to coincide with an airspace-filling pattern of growth in the main tumor mass.

Source: NCI Genomic Data Commons file 13e0845c-4229-4312-8434-1c4b185ea2d1 (TCGA-34-5241.9D9A1BBA-2489-40B3-BAD8-950BC742862D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).